Somatic mutation profile of tumor specimen C3L-00965-03 (aliquot CPT0101130009) from CPTAC case C3L-00965, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 63.8 years (23,305 days).
Specimen C3L-00965-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9d5a6433-79da-4f8a-8474-b379e3e9baf1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00965-31 (Blood Derived Normal), aliquot CPT0100930002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bc57585c-130c-4239-aa59-d9347d562e71

The open-access MAF lists 407 somatic variants for this specimen: 277 protein-altering or splice-affecting, 84 silent, 46 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 233, Silent 84, Intron 22, Nonsense Mutation 18, Frame Shift Del 10, Splice Site 9, RNA 9, 5'UTR 5, Splice Region 4, 5'Flank 4, 3'UTR 3, Frame Shift Ins 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 54/332 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs138398778, CM0910483, COSV53723836, COSV53775938; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KEAP1 | c.1409G>A p.R470H | Missense Mutation (SNP) | VAF 128/400 reads (32%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen probably damaging (0.956); catalogued as COSV50285556; called by muse, mutect2
- TP53 | c.406C>T p.Q136* | Nonsense Mutation (SNP) | VAF 110/269 reads (41%) | hotspot (GDC flag); catalogued as CM971503, COSV52676850, COSV52715987, COSV52740951; called by muse, mutect2, varscan2
- ABCA10 | c.949G>A p.A317T | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.088); catalogued as rs748559641; called by muse, mutect2, varscan2
- ABCA13 | c.7875G>A p.M2625I | Missense Mutation (SNP) | VAF 116/385 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs1320861757; called by muse, mutect2, varscan2
- AC068580.4 | c.1037G>A p.G346D | Missense Mutation (SNP) | VAF 25/222 reads (11%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.006); catalogued as COSV52588010; called by muse, mutect2, varscan2
- ADAD1 | c.1661C>G p.S554C | Missense Mutation (SNP) | VAF 24/176 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as COSV56647256; called by muse, mutect2, varscan2
- ADAM2 | c.2020C>A p.R674S | Missense Mutation (SNP) | VAF 58/286 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as COSV55864569; called by muse, varscan2
- ADAMTS12 | c.2062G>A p.E688K | Missense Mutation (SNP) | VAF 66/271 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs115179442; called by muse, mutect2, varscan2
- AGBL1 | c.2842C>G p.L948V | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT tolerated (0.58); PolyPhen benign (0.312); catalogued as COSV101222326; called by muse, varscan2
- AMY1C | c.1003C>A p.L335M | Missense Mutation (SNP) | VAF 38/390 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.208); catalogued as rs778192509, COSV100915244; called by muse, varscan2
- AP2A2 | c.2072C>T p.S691L | Missense Mutation (SNP) | VAF 89/295 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1286659177; called by muse, mutect2, varscan2
- C6orf163 | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.236); catalogued as rs529190200; called by muse, mutect2
- CCDC65 | c.386C>T p.A129V | Missense Mutation (SNP) | VAF 56/218 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs1325927739; called by muse, mutect2
- CDC42BPA | c.5035A>G p.S1679G (on ENST00000334218 / NM_001366019.2; = p.S1666G on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs746579028, COSV100507123; called by mutect2, varscan2
- CDK5RAP2 | c.531A>T p.E177D | Missense Mutation (SNP) | VAF 16/512 reads (3%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.987); catalogued as rs1212225147; called by muse, mutect2
- CDKN2A | c.68G>T p.G23V | Missense Mutation (SNP) | VAF 76/190 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM980322, COSV58684053, COSV58729667; called by muse, mutect2, varscan2
- CEACAM21 | c.847C>A p.P283T (on ENST00000401445 / NM_001098506.4; = p.P282T on NM_033543.6) | Missense Mutation (SNP) | VAF 53/117 reads (45%) | SIFT tolerated (0.63); PolyPhen benign (0.08); catalogued as rs1232057161, COSV99494629; called by muse, mutect2, varscan2
- CEP170B | c.775G>T p.G259* (on ENST00000453495; = p.G188* on NM_015005.3) | Nonsense Mutation (SNP) | VAF 51/218 reads (23%) | catalogued as COSV69026748; called by muse, mutect2, varscan2
- CFHR5 | c.904G>T p.A302S | Missense Mutation (SNP) | VAF 48/336 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as COSV56827808; called by muse, mutect2, varscan2
- CHD9 | c.8489A>G p.K2830R (on ENST00000398510 / NM_001382353.1; = p.K2814R on NM_025134.7) | Missense Mutation (SNP) | VAF 55/137 reads (40%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.708); catalogued as rs761741353; called by muse, mutect2, varscan2
- CNGA4 | c.697G>T p.G233C | Missense Mutation (SNP) | VAF 87/434 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66006434; called by muse, mutect2, varscan2
- COL11A1 | c.5263G>A p.D1755N | Missense Mutation (SNP) | VAF 85/228 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100618047; called by muse, mutect2, varscan2
- COL22A1 | c.2482G>A p.G828R | Missense Mutation (SNP) | VAF 62/258 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57357012; called by muse, mutect2, varscan2
- CTNND2 | c.1411C>T p.R471C | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs905659484, COSV58934168; called by muse, varscan2
- CYB5R2 | c.416C>T p.T139M | Missense Mutation (SNP) | VAF 34/414 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.018); catalogued as rs780160716; called by muse, mutect2
- DACH1 | c.2246G>T p.R749I (on ENST00000619232 / NM_001366712.1; = p.R495I on NM_004392.6) | Missense Mutation (SNP) | VAF 55/170 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.05); catalogued as COSV57521979; called by muse, mutect2, varscan2
- DCTN1 | c.178G>A p.V60M | Missense Mutation (SNP) | VAF 83/747 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as rs74768853, COSV62621486; called by muse, mutect2, varscan2
- DISP2 | c.1936C>A p.R646S | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs764597052; called by muse, mutect2, varscan2
- DNAH8 | c.10412C>T p.P3471L | Missense Mutation (SNP) | VAF 35/258 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59427152; called by muse, mutect2, varscan2
- DSEL | c.3479C>G p.S1160C | Missense Mutation (SNP) | VAF 87/199 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV59491021; called by muse, mutect2, varscan2
- EMILIN3 | c.1559C>T p.S520L | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs963809181, COSV60035976; called by muse, mutect2, varscan2
- FAM151A | c.404C>T p.S135F | Missense Mutation (SNP) | VAF 165/388 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); catalogued as COSV56362847; called by muse, mutect2, varscan2
- FN3K | c.389G>T p.R130L | Missense Mutation (SNP) | VAF 163/583 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs758064945; called by muse, mutect2, varscan2
- FRZB | c.575G>A p.R192Q | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.227); catalogued as rs766968251; called by muse, mutect2, varscan2
- GABRA6 | c.1138C>A p.P380T | Missense Mutation (SNP) | VAF 106/218 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.085); catalogued as COSV50890341; called by muse, mutect2, varscan2
- GABRG1 | c.828G>T p.Q276H | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.873); catalogued as COSV54950918; called by muse, mutect2, varscan2
- GGT2 | c.482T>C p.I161T | Missense Mutation (SNP) | VAF 34/142 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1246372553; called by muse, mutect2, varscan2
- GRB14 | c.1489G>T p.G497C | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55737813; called by muse, mutect2, varscan2
- GRB14 | c.724C>T p.H242Y | Missense Mutation (SNP) | VAF 29/128 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.129); catalogued as rs771370778, COSV55735960; called by muse, mutect2, varscan2
- HECW1 | c.172del p.H58Tfs*45 | Frame Shift Del (DEL) | VAF 120/436 reads (28%) | catalogued as COSV101222597; called by mutect2, pindel, varscan2
- HIPK2 | c.137C>T p.S46F | Missense Mutation (SNP) | VAF 89/302 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.084); catalogued as rs959052812; called by muse, mutect2, varscan2
- IL17RA | c.2584G>C p.E862Q | Missense Mutation (SNP) | VAF 43/337 reads (13%) | SIFT tolerated, low confidence (0.46); PolyPhen possibly damaging (0.857); catalogued as COSV100083063; called by muse, mutect2, varscan2
- IMPG1 | c.1156G>A p.A386T | Missense Mutation (SNP) | VAF 68/212 reads (32%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs757303082, COSV64058387; called by muse, mutect2, varscan2
- KDR | c.1588T>G p.C530G | Missense Mutation (SNP) | VAF 91/607 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55768072; called by muse, mutect2, varscan2
- KIF2B | c.882G>C p.K294N | Missense Mutation (SNP) | VAF 91/340 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as COSV52134212, COSV52136276; called by muse, mutect2, varscan2
- LGALS13 | c.124A>G p.T42A | Missense Mutation (SNP) | VAF 20/506 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs890376495; called by muse, mutect2
- LILRB4 | c.417C>G p.S139R | Missense Mutation (SNP) | VAF 100/184 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as COSV54403159; called by muse, mutect2, varscan2
- LPIN2 | c.639G>T p.L213F | Missense Mutation (SNP) | VAF 13/253 reads (5%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV55236439; called by muse, mutect2
- LRP2 | c.7136G>A p.G2379D | Missense Mutation (SNP) | VAF 66/446 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.036); catalogued as rs754795839; called by muse, varscan2
- MAS1L | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 53/307 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.698); catalogued as rs768922382, COSV65809104; called by muse, mutect2, varscan2
- MCHR2 | c.551G>A p.C184Y | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99029591; called by muse, mutect2, varscan2
- MED12 | c.5576G>A p.R1859H | Missense Mutation (SNP) | VAF 103/208 reads (50%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.991); catalogued as rs763700798, COSV61347042; called by muse, mutect2, varscan2
- MFSD8 | c.478A>G p.T160A | Missense Mutation (SNP) | VAF 76/402 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1161204187; called by muse, mutect2, varscan2
- MTF2 | c.1720C>G p.R574G | Missense Mutation (SNP) | VAF 85/182 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64770957; called by muse, mutect2, varscan2
- MTUS2 | c.442G>T p.A148S | Missense Mutation (SNP) | VAF 101/228 reads (44%) | SIFT tolerated (0.78); PolyPhen benign (0.027); catalogued as COSV70914556; called by muse, mutect2, varscan2
- MUC16 | c.26336C>G p.T8779R | Missense Mutation (SNP) | VAF 106/280 reads (38%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.001); catalogued as COSV101199296; called by muse, mutect2, varscan2
- NCOA6 | c.3353C>T p.P1118L | Missense Mutation (SNP) | VAF 112/1424 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs767151504, COSV62861256; called by muse, mutect2
- NCOA7 | c.1339C>G p.R447G | Missense Mutation (SNP) | VAF 28/184 reads (15%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.011); catalogued as rs958030764; called by muse, mutect2, varscan2
- NLGN1 | c.2339C>G p.T780S | Missense Mutation (SNP) | VAF 103/442 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.869); catalogued as COSV99053738; called by muse, mutect2, varscan2
- ODF2 | c.731C>T p.T244M (on ENST00000434106 / NM_153433.2; = p.T220M on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 83/186 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.868); catalogued as rs1304376183; called by muse, mutect2, varscan2
- OR51I2 | c.541C>T p.H181Y | Missense Mutation (SNP) | VAF 108/317 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58298854; called by muse, mutect2, varscan2
- OR56A4 | c.406G>T p.V136F | Missense Mutation (SNP) | VAF 67/205 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV58109081; called by muse, mutect2, varscan2
- OR5L1 | c.482G>C p.C161S | Missense Mutation (SNP) | VAF 73/348 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.163); catalogued as COSV100449865; called by muse, mutect2, varscan2
- OR5T2 | c.595A>G p.T199A | Missense Mutation (SNP) | VAF 54/170 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.458); catalogued as rs1364024953; called by muse, mutect2, varscan2
- OR5T2 | c.157C>A p.L53M | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV57588681; called by muse, mutect2, varscan2
- PAF1 | c.29A>T p.Q10L | Missense Mutation (SNP) | VAF 93/190 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1341345269; called by muse, mutect2, varscan2
- PCDHB3 | c.1970C>A p.T657K | Missense Mutation (SNP) | VAF 202/479 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.843); catalogued as COSV99166719; called by muse, mutect2, varscan2
- PCDHB7 | c.125del p.G42Afs*11 | Frame Shift Del (DEL) | VAF 117/305 reads (38%) | catalogued as COSV50818417; called by mutect2, pindel, varscan2
- PCDHGA1 | c.1883C>T p.T628M | Missense Mutation (SNP) | VAF 170/364 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.957); catalogued as rs747200046, COSV100966071, COSV65296718; called by muse, mutect2, varscan2
- PIH1D2 | c.461G>A p.R154K | Missense Mutation (SNP) | VAF 74/259 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99735511; called by muse, mutect2, varscan2
- PITPNM2 | c.3688G>T p.V1230L | Missense Mutation (SNP) | VAF 52/136 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV54906780; called by muse, mutect2, varscan2
- PKHD1L1 | c.196G>T p.V66F | Missense Mutation (SNP) | VAF 97/331 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.076); catalogued as rs527462333; called by muse, mutect2, varscan2
- PLOD1 | c.1825G>T p.E609* | Nonsense Mutation (SNP) | VAF 248/590 reads (42%) | catalogued as rs1464654878, COSV52142657, COSV99539276; called by muse, mutect2, varscan2
- PROX1 | c.1498C>G p.P500A | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (1); PolyPhen possibly damaging (0.652); catalogued as rs765587710; called by muse, mutect2, varscan2
- PSD3 | c.2570C>T p.T857M (on ENST00000440756; = p.T856M on NM_015310.4) | Missense Mutation (SNP) | VAF 96/370 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.608); catalogued as rs763481193, COSV54075429; called by muse, varscan2
- PTH2R | c.1456C>A p.P486T | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs1248089140, COSV55913414; called by muse, mutect2, varscan2
- PTK2B | c.1837G>A p.V613M | Missense Mutation (SNP) | VAF 118/336 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs754472545, COSV57752482, COSV57763138; called by muse, mutect2, varscan2
- PYGM | c.1274G>T p.R425L | Missense Mutation (SNP) | VAF 159/526 reads (30%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.975); catalogued as rs368608057; called by muse, mutect2, varscan2
- RAG2 | c.1261C>G p.P421A | Missense Mutation (SNP) | VAF 128/584 reads (22%) | SIFT tolerated (0.97); PolyPhen benign (0.024); catalogued as COSV57557325; called by muse, mutect2, varscan2
- RBP1 | c.75C>T p.D25= (on ENST00000619087 / NM_001365940.2; = p.D87= on NM_002899.5) | Splice Region (SNP) | VAF 41/327 reads (13%) | catalogued as rs780486919; called by muse, mutect2, varscan2
- REG1B | c.241G>T p.G81C | Missense Mutation (SNP) | VAF 74/267 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as rs1290021844; called by muse, varscan2
- RIMKLB | c.557A>G p.H186R | Missense Mutation (SNP) | VAF 52/515 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0.143); catalogued as rs1268715870, COSV55235293; called by muse, mutect2, varscan2
- RIPOR3 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 100/318 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs762795338; called by muse, mutect2, varscan2
- RNF123 | c.1297G>A p.V433I | Missense Mutation (SNP) | VAF 36/175 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.094); catalogued as rs750955001; called by muse, mutect2, varscan2
- RTN1 | c.1308C>A p.H436Q | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.446); catalogued as COSV99954845; called by muse, mutect2, varscan2
- SEL1L2 | c.1876C>T p.H626Y | Missense Mutation (SNP) | VAF 108/336 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV53148732; called by muse, mutect2, varscan2
- SEMA5A | c.392G>T p.C131F | Missense Mutation (SNP) | VAF 39/441 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV66798547; called by muse, mutect2
- SHANK2 | c.3256G>A p.V1086I | Missense Mutation (SNP) | VAF 24/184 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1555154083, COSV53618934; called by muse, mutect2, varscan2
- SHISA9 | c.418G>T p.D140Y | Missense Mutation (SNP) | VAF 155/323 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV101376126; called by muse, mutect2, varscan2
- SLITRK3 | c.1732G>A p.E578K | Missense Mutation (SNP) | VAF 22/422 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.469); catalogued as rs998593651, COSV53846053; called by muse, mutect2
- SOX6 | c.1168C>T p.Q390* (on ENST00000528429 / NM_001145819.2; = p.Q349* on NM_017508.3) | Nonsense Mutation (SNP) | VAF 112/382 reads (29%) | catalogued as COSV57044135; called by muse, varscan2
- SPTBN2 | c.1567C>T p.R523W | Missense Mutation (SNP) | VAF 38/209 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs374206914; called by muse, mutect2, varscan2
- SPTY2D1 | c.1501C>T p.P501S | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs755900924; called by muse, mutect2, varscan2
- SRRM4 | c.619C>A p.R207S | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.58); catalogued as rs368516977; called by muse, mutect2, varscan2
- SUCLG2 | c.401G>A p.G134D | Missense Mutation (SNP) | VAF 69/175 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750025421; called by muse, mutect2, varscan2
- TBX4 | c.749G>A p.R250Q | Missense Mutation (SNP) | VAF 116/367 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1555883469; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TEX13A | c.569G>T p.G190V | Missense Mutation (SNP) | VAF 55/121 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as COSV61185424; called by muse, mutect2, varscan2
- TNN | c.3001del p.H1001Tfs*5 | Frame Shift Del (DEL) | VAF 45/256 reads (18%) | catalogued as COSV53434458; called by mutect2, pindel, varscan2
- TPTE | c.417G>T p.M139I (on ENST00000618007 / NM_199261.4; = p.M121I on NM_199259.4) | Missense Mutation (SNP) | VAF 41/205 reads (20%) | SIFT tolerated (0.64); PolyPhen benign (0.023); catalogued as rs756602065; called by mutect2, varscan2
- TRIO | c.8153G>C p.W2718S | Missense Mutation (SNP) | VAF 107/357 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1369497590; called by muse, mutect2, varscan2
- TTN | c.63272C>T p.S21091L (on ENST00000591111; = p.S13667L on NM_003319.4) | Missense Mutation (SNP) | VAF 17/115 reads (15%) | PolyPhen possibly damaging (0.455); catalogued as rs727505352, COSV59896018; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- TTN | c.50803C>G p.P16935A (on ENST00000591111; = p.P9511A on NM_003319.4) | Missense Mutation (SNP) | VAF 9/52 reads (17%) | PolyPhen probably damaging (0.997); catalogued as rs934495490; called by muse, mutect2, varscan2
- TTN | c.49481G>A p.G16494D (on ENST00000591111; = p.G9070D on NM_003319.4) | Missense Mutation (SNP) | VAF 10/31 reads (32%) | PolyPhen benign (0.009); catalogued as rs776471324; called by muse, mutect2, varscan2
- UBE3A | c.1648G>T p.D550Y | Missense Mutation (SNP) | VAF 59/277 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51666916; called by muse, mutect2, varscan2
- VSIR | c.827G>T p.R276L | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV56460154; called by muse, mutect2, varscan2
- WT1 | c.314C>A p.A105E | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.423); catalogued as rs948061247, CM134065; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF133 | c.863A>T p.H288L (on ENST00000316358 / NM_001352454.2; = p.H287L on NM_003434.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/120 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60368291; called by muse, mutect2, varscan2
- ZNF418 | c.1844G>A p.R615Q | Missense Mutation (SNP) | VAF 160/339 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs766509478; called by muse, mutect2, varscan2
- ZNF548 | c.19C>T p.R7C | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs766710560; called by muse, mutect2, varscan2
- ABCB10 | c.792C>A p.D264E | Missense Mutation (SNP) | VAF 101/412 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- ABCB5 | c.2983A>G p.K995E (on ENST00000404938 / NM_001163941.2; = p.K550E on NM_178559.6) | Missense Mutation (SNP) | VAF 40/163 reads (25%) | SIFT tolerated (0.8); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ADAM20 | c.1351A>C p.I451L | Missense Mutation (SNP) | VAF 48/382 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADGRB3 | c.1130A>G p.Y377C | Missense Mutation (SNP) | VAF 52/151 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- ADGRB3 | c.2504C>G p.S835C | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- AHNAK2 | c.4865C>G p.S1622C | Missense Mutation (SNP) | VAF 157/695 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- AJM1 | c.215C>T p.P72L | Missense Mutation (SNP) | VAF 83/164 reads (51%) | SIFT tolerated (0.16); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- AKAP11 | c.2569A>T p.I857F | Missense Mutation (SNP) | VAF 79/189 reads (42%) | SIFT tolerated (0.64); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- ANK2 | c.2031G>T p.M677I | Missense Mutation (SNP) | VAF 124/331 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.421); called by muse, mutect2, varscan2
- ANKRD20A4P | c.2044A>T p.R682* | Nonsense Mutation (SNP) | VAF 140/504 reads (28%) | called by muse, varscan2
- APOB | c.6241T>A p.F2081I | Missense Mutation (SNP) | VAF 28/302 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.101); called by muse, mutect2
- APOB | c.2121G>T p.K707N | Missense Mutation (SNP) | VAF 75/466 reads (16%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AR | c.886G>C p.D296H | Missense Mutation (SNP) | VAF 76/168 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- ARHGAP11A | c.1001C>A p.S334Y | Missense Mutation (SNP) | VAF 32/162 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- ARHGEF38 | c.476C>G p.T159R | Missense Mutation (SNP) | VAF 27/209 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- ASCC3 | c.5896A>C p.N1966H | Missense Mutation (SNP) | VAF 44/300 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BAMBI | c.434C>T p.S145F | Missense Mutation (SNP) | VAF 48/162 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- BTK | c.1257del p.K420Nfs*12 | Frame Shift Del (DEL) | VAF 54/139 reads (39%) | called by mutect2, pindel, varscan2
- CACNG2 | c.797C>A p.T266K | Missense Mutation (SNP) | VAF 138/308 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- CASD1 | c.1753A>T p.K585* | Nonsense Mutation (SNP) | VAF 67/216 reads (31%) | called by muse, mutect2, varscan2
- CCDC152 | c.176A>T p.E59V | Missense Mutation (SNP) | VAF 73/254 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CCDC39 | c.1456G>T p.E486* | Nonsense Mutation (SNP) | VAF 73/421 reads (17%) | called by muse, mutect2, varscan2
- CDH10 | c.1552C>A p.P518T | Missense Mutation (SNP) | VAF 60/211 reads (28%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- CDH4 | c.2424C>G p.H808Q | Missense Mutation (SNP) | VAF 59/201 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- CDH7 | c.1141T>A p.L381M | Missense Mutation (SNP) | VAF 28/181 reads (15%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- CDK5RAP2 | c.5231G>T p.G1744V | Missense Mutation (SNP) | VAF 105/201 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- CFHR3 | c.283G>T p.G95* | Nonsense Mutation (SNP) | VAF 41/107 reads (38%) | called by muse, mutect2, varscan2
- CLCN1 | c.2199del p.S734Lfs*60 | Frame Shift Del (DEL) | VAF 113/414 reads (27%) | called by mutect2, pindel, varscan2
- CNTNAP3 | c.3792A>G p.I1264M | Missense Mutation (SNP) | VAF 135/1606 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.125); called by muse, mutect2
- COL11A1 | c.2869C>T p.Q957* | Nonsense Mutation (SNP) | VAF 82/205 reads (40%) | called by muse, mutect2, varscan2
- COL19A1 | c.1280dup p.X427_splice | Splice Site (INS) | VAF 27/219 reads (12%) | called by mutect2, pindel, varscan2
- COL22A1 | c.4853C>A p.A1618D | Missense Mutation (SNP) | VAF 80/312 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- CRISPLD1 | c.362G>T p.G121V | Missense Mutation (SNP) | VAF 98/198 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CRTAM | c.1071C>G p.C357W | Missense Mutation (SNP) | VAF 39/154 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- CSMD1 | c.5965C>A p.P1989T (on ENST00000520002; = p.P1988T on NM_033225.6) | Missense Mutation (SNP) | VAF 127/300 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CTBP2 | c.967G>T p.A323S | Missense Mutation (SNP) | VAF 45/79 reads (57%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.644); called by muse, mutect2, varscan2
- DACT1 | c.472A>T p.S158C | Missense Mutation (SNP) | VAF 46/162 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DCAF15 | c.473+1G>A p.X158_splice | Splice Site (SNP) | VAF 49/216 reads (23%) | called by muse, mutect2, varscan2
- DCDC2 | c.660C>A p.Y220* | Nonsense Mutation (SNP) | VAF 41/202 reads (20%) | called by muse, mutect2, varscan2
- DDX3X | c.1542T>G p.N514K (on ENST00000399959; = p.N515K on NM_001356.5) | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DIPK1C | c.478G>T p.G160C | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- DMBT1 | c.7553A>G p.Y2518C (on ENST00000338354 / NM_001377530.1; = p.Y1761C on NM_004406.3) | Missense Mutation (SNP) | VAF 129/282 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- DTNA | c.953C>T p.P318L | Missense Mutation (SNP) | VAF 228/542 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, varscan2
- EFCAB6 | c.2659G>C p.E887Q | Missense Mutation (SNP) | VAF 81/183 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ELOVL4 | c.914dup p.Q306Afs*12 | Frame Shift Ins (INS) | VAF 48/368 reads (13%) | called by mutect2, pindel, varscan2
- EPHA3 | c.2735C>T p.T912I | Missense Mutation (SNP) | VAF 54/123 reads (44%) | SIFT tolerated (0.24); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- ESRRG | c.574G>T p.G192C | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EYS | c.4378G>C p.V1460L | Missense Mutation (SNP) | VAF 61/377 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- FAM189A1 | c.899C>A p.A300E | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FAM47C | c.2095G>T p.V699L | Missense Mutation (SNP) | VAF 117/242 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- FBF1 | c.1943G>T p.R648L (on ENST00000586717; = p.R662L on NM_001319193.1) | Missense Mutation (SNP) | VAF 153/459 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- FBN1 | c.1337C>T p.P446L | Missense Mutation (SNP) | VAF 98/401 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- FLT1 | c.1285C>A p.Q429K | Missense Mutation (SNP) | VAF 154/372 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- FLT3 | c.1797T>A p.Y599* | Nonsense Mutation (SNP) | VAF 64/156 reads (41%) | called by muse, mutect2, varscan2
- FOXO3 | c.361G>C p.G121R | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- FTO | c.124-1G>A p.X42_splice | Splice Site (SNP) | VAF 113/274 reads (41%) | called by muse, mutect2, varscan2
- GATA3 | c.1019C>A p.A340D | Missense Mutation (SNP) | VAF 107/374 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GDPD2 | c.63C>A p.C21* | Nonsense Mutation (SNP) | VAF 33/74 reads (45%) | called by muse, mutect2, varscan2
- GLA | c.410T>A p.V137D | Missense Mutation (SNP) | VAF 77/175 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- GOLGA6L10 | c.1190G>C p.R397P | Missense Mutation (SNP) | VAF 163/1168 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- GOLGA6L2 | c.1846G>C p.G616R | Missense Mutation (SNP) | VAF 137/604 reads (23%) | SIFT deleterious, low confidence (0.05); called by muse, mutect2, varscan2
- GOLGA6L2 | c.1531G>T p.E511* | Nonsense Mutation (SNP) | VAF 117/331 reads (35%) | called by mutect2, varscan2
- GPR37 | c.619C>A p.H207N | Missense Mutation (SNP) | VAF 8/123 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2
- GRM1 | c.1964C>A p.T655N | Missense Mutation (SNP) | VAF 64/177 reads (36%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.457); called by muse, mutect2, varscan2
- HEPACAM2 | c.1148A>C p.Q383P (on ENST00000394468 / NM_001039372.4; = p.Q371P on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- HSPA4 | c.2320G>T p.E774* | Nonsense Mutation (SNP) | VAF 110/227 reads (48%) | called by muse, mutect2, varscan2
- HTR2C | c.196A>C p.M66L | Missense Mutation (SNP) | VAF 75/166 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- HYDIN | c.7537A>T p.R2513* | Nonsense Mutation (SNP) | VAF 137/278 reads (49%) | called by muse, mutect2, varscan2
- IDE | c.854T>C p.L285S | Missense Mutation (SNP) | VAF 69/172 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- IGHV1-24 | c.14G>T p.W5L | Missense Mutation (SNP) | VAF 52/218 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.529); called by mutect2, varscan2
- IKZF1 | c.160+3_160+10del p.X54_splice | Splice Site (DEL) | VAF 32/105 reads (30%) | called by mutect2, pindel, varscan2
- INPPL1 | c.2927del p.P976Hfs*155 | Frame Shift Del (DEL) | VAF 12/79 reads (15%) | called by mutect2, pindel
- IREB2 | c.938C>T p.T313I | Missense Mutation (SNP) | VAF 26/316 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.07); called by muse, mutect2
- KATNIP | c.141G>T p.R47= | Splice Region (SNP) | VAF 55/111 reads (50%) | called by muse, mutect2, varscan2
- KCNU1 | c.695T>A p.L232H | Missense Mutation (SNP) | VAF 138/313 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- KDM3A | c.2599C>T p.H867Y | Missense Mutation (SNP) | VAF 62/376 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- KIF21A | c.4299dup p.G1434Wfs*47 (on ENST00000361418 / NM_001378440.1; = p.G1421Wfs*47 on NM_017641.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 70/430 reads (16%) | called by mutect2, pindel, varscan2
- KLHL29 | c.1847A>G p.Y616C | Missense Mutation (SNP) | VAF 67/378 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- KMT2D | c.4802del p.R1601Lfs*3 | Frame Shift Del (DEL) | VAF 41/246 reads (17%) | called by mutect2, pindel, varscan2
- KYNU | c.1013T>C p.L338S | Missense Mutation (SNP) | VAF 70/392 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- LAMA1 | c.8051A>T p.D2684V | Missense Mutation (SNP) | VAF 16/338 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.006); called by muse, mutect2
- LILRB5 | c.632A>C p.D211A | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- LPP | c.726A>T p.Q242H | Missense Mutation (SNP) | VAF 138/430 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LRP4 | c.2974A>G p.I992V | Missense Mutation (SNP) | VAF 54/221 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- LRRC9 | c.348A>T p.L116F | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by mutect2, varscan2
- MALRD1 | c.4190C>A p.A1397E | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.672); called by muse, mutect2, varscan2
- MARCHF11 | c.996A>T p.E332D | Missense Mutation (SNP) | VAF 136/474 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- MDGA2 | c.383A>T p.E128V | Missense Mutation (SNP) | VAF 74/289 reads (26%) | SIFT tolerated (1); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- MFF | c.639G>T p.M213I | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- MGAM2 | c.2220+1G>T p.X740_splice | Splice Site (SNP) | VAF 31/199 reads (16%) | called by muse, mutect2, varscan2
- MRNIP | c.170A>C p.Q57P | Missense Mutation (SNP) | VAF 30/219 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MUC16 | c.19877C>G p.S6626C | Missense Mutation (SNP) | VAF 84/262 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- MYH4 | c.3985G>T p.A1329S | Missense Mutation (SNP) | VAF 49/128 reads (38%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- MYO7A | c.889G>T p.E297* | Nonsense Mutation (SNP) | VAF 24/93 reads (26%) | called by muse, mutect2, varscan2
- MYO7B | c.3947C>T p.S1316F | Missense Mutation (SNP) | VAF 34/189 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NCOA3 | c.728A>T p.Q243L | Missense Mutation (SNP) | VAF 73/209 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- NIPBL | c.1496-1G>A p.X499_splice | Splice Site (SNP) | VAF 36/152 reads (24%) | called by muse, mutect2, varscan2
- NLRP9 | c.1769A>C p.H590P | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NSD3 | c.2677C>G p.L893V | Missense Mutation (SNP) | VAF 111/270 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- NUGGC | c.1633T>C p.F545L | Missense Mutation (SNP) | VAF 190/533 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.226); called by muse, mutect2, varscan2
- ODAM | c.590G>T p.G197V | Missense Mutation (SNP) | VAF 80/272 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.545); called by muse, mutect2, varscan2
- OR11H2 | c.170G>T p.R57L (on ENST00000556246; = p.R68L on NM_001197287.1) | Missense Mutation (SNP) | VAF 118/711 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR2T34 | c.529A>T p.R177W | Missense Mutation (SNP) | VAF 47/256 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- OR4E2 | c.516C>A p.N172K | Missense Mutation (SNP) | VAF 52/173 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- OR4K5 | c.136A>T p.I46F | Missense Mutation (SNP) | VAF 89/510 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- OR4K5 | c.761G>C p.C254S | Missense Mutation (SNP) | VAF 122/548 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- OS9 | c.1548_1549del p.H516Qfs*22 | Frame Shift Del (DEL) | VAF 25/226 reads (11%) | called by pindel, varscan2
- OTOG | c.1945G>T p.V649L | Missense Mutation (SNP) | VAF 48/216 reads (22%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- PAX6 | c.1002C>A p.S334R | Missense Mutation (SNP) | VAF 189/653 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- PCDH11X | c.946G>C p.D316H | Missense Mutation (SNP) | VAF 42/155 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDH11Y | c.1031A>G p.K344R (on ENST00000400457 / NM_032973.2; = p.K333R on NM_032971.3) | Missense Mutation (SNP) | VAF 41/155 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.291); called by muse, mutect2, varscan2
- PDZRN3 | c.844T>A p.F282I | Missense Mutation (SNP) | VAF 64/156 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- PI16 | c.1309C>A p.L437M | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- PKHD1L1 | c.1567G>T p.A523S | Missense Mutation (SNP) | VAF 53/169 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- POLR1D | c.50C>T p.S17L | Missense Mutation (SNP) | VAF 85/164 reads (52%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- POTEC | c.80G>T p.W27L | Missense Mutation (SNP) | VAF 174/428 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.709); called by muse, mutect2, varscan2
- PPFIA2 | c.-3+1G>T | Splice Site (SNP) | VAF 23/124 reads (19%) | called by muse, mutect2, varscan2
- PRPF4 | c.1040G>C p.R347P (on ENST00000374198 / NM_001322267.2; = p.R348P on NM_004697.5) | Missense Mutation (SNP) | VAF 10/234 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PRPF4B | c.140A>T p.K47M | Missense Mutation (SNP) | VAF 22/175 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PRR32 | c.791C>A p.P264H | Missense Mutation (SNP) | VAF 56/195 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- PTPN4 | c.2177G>T p.C726F | Missense Mutation (SNP) | VAF 59/297 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- REC8 | c.737+5G>C | Splice Region (SNP) | VAF 88/346 reads (25%) | called by muse, mutect2, varscan2
- REG1A | c.184-2A>T p.X62_splice | Splice Site (SNP) | VAF 34/146 reads (23%) | called by muse, mutect2, varscan2
- REV1 | c.3370G>A p.A1124T | Missense Mutation (SNP) | VAF 29/235 reads (12%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- RIN1 | c.377C>G p.P126R | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.11); called by muse, mutect2
- RNF123 | c.749G>T p.G250V | Missense Mutation (SNP) | VAF 53/124 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RPIA | c.32A>G p.Y11C | Missense Mutation (SNP) | VAF 56/120 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- RXFP4 | c.457del p.L153Sfs*8 | Frame Shift Del (DEL) | VAF 33/179 reads (18%) | called by mutect2, pindel, varscan2
- SALL1 | c.3023A>T p.K1008I | Missense Mutation (SNP) | VAF 291/678 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SEC14L2 | c.579A>G p.K193= | Splice Region (SNP) | VAF 106/262 reads (40%) | called by muse, varscan2
- SERTAD4 | c.581A>C p.E194A | Missense Mutation (SNP) | VAF 13/386 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.275); called by muse, mutect2
- SLC22A2 | c.232C>A p.P78T | Missense Mutation (SNP) | VAF 21/152 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- SLC24A4 | c.1228G>A p.D410N | Missense Mutation (SNP) | VAF 101/314 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC5A7 | c.1195A>G p.T399A | Missense Mutation (SNP) | VAF 104/292 reads (36%) | SIFT tolerated (0.43); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLCO1B3 | c.34G>T p.E12* | Nonsense Mutation (SNP) | VAF 68/164 reads (41%) | called by muse, mutect2, varscan2
- SLITRK4 | c.677C>A p.A226D | Missense Mutation (SNP) | VAF 95/205 reads (46%) | SIFT tolerated (0.37); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- SNTB2 | c.1258G>T p.E420* | Nonsense Mutation (SNP) | VAF 63/147 reads (43%) | called by muse, mutect2, varscan2
- SP1 | c.1175A>T p.Q392L (on ENST00000327443 / NM_138473.3; = p.Q385L on NM_003109.1) | Missense Mutation (SNP) | VAF 74/413 reads (18%) | SIFT tolerated (0.81); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- SPATA31D1 | c.623T>C p.L208S | Missense Mutation (SNP) | VAF 200/489 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- SPTA1 | c.5262G>T p.K1754N | Missense Mutation (SNP) | VAF 132/413 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- SSH1 | c.1247dup p.E417Gfs*5 | Frame Shift Ins (INS) | VAF 128/401 reads (32%) | called by mutect2, pindel, varscan2
- SYNM | c.2269A>G p.S757G | Missense Mutation (SNP) | VAF 58/252 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TCHH | c.4985G>T p.R1662L | Missense Mutation (SNP) | VAF 70/462 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- TDRD5 | c.2229C>A p.N743K | Missense Mutation (SNP) | VAF 56/147 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TECPR2 | c.352_355del p.R118Dfs*22 | Frame Shift Del (DEL) | VAF 36/108 reads (33%) | called by mutect2, pindel, varscan2
- TMC5 | c.1253A>T p.K418M (on ENST00000396229 / NM_001105248.1; = p.K172M on NM_024780.5) | Missense Mutation (SNP) | VAF 59/118 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- TMEM41A | c.323G>T p.C108F | Missense Mutation (SNP) | VAF 88/299 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- TPTE | c.418G>T p.D140Y (on ENST00000618007 / NM_199261.4; = p.D122Y on NM_199259.4) | Missense Mutation (SNP) | VAF 41/215 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRPV5 | c.1711C>A p.L571I | Missense Mutation (SNP) | VAF 28/199 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- TTN | c.84593T>C p.I28198T (on ENST00000591111; = p.I20774T on NM_003319.4) | Missense Mutation (SNP) | VAF 12/53 reads (23%) | PolyPhen possibly damaging (0.52); called by muse, mutect2, varscan2
- TTN | c.28607C>A p.A9536E (on ENST00000591111; = p.A8609E on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/207 reads (18%) | PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TUBA3E | c.712A>T p.I238F | Missense Mutation (SNP) | VAF 105/417 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- USH2A | c.7385A>T p.N2462I | Missense Mutation (SNP) | VAF 133/492 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USH2A | c.3730C>G p.Q1244E | Missense Mutation (SNP) | VAF 37/205 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- USP5 | c.1946C>G p.S649C | Missense Mutation (SNP) | VAF 21/171 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.552); called by muse, mutect2, varscan2
- VPS35L | c.2369C>G p.P790R | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- VPS39 | c.2494G>A p.V832I (on ENST00000348544 / NM_001301138.2; = p.V821I on NM_015289.5) | Missense Mutation (SNP) | VAF 48/203 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- ZBBX | c.1940G>C p.S647T | Missense Mutation (SNP) | VAF 71/250 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- ZNF208 | c.3130C>A p.L1044I | Missense Mutation (SNP) | VAF 62/345 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- ZNF385B | c.1152C>A p.S384R | Missense Mutation (SNP) | VAF 51/289 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF440 | c.1721G>T p.R574M | Missense Mutation (SNP) | VAF 75/184 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- ZNF654 | c.178T>C p.F60L | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- ZNF729 | c.100C>A p.Q34K | Missense Mutation (SNP) | VAF 45/215 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- ZNF77 | c.3+1G>C p.X1_splice | Splice Site (SNP) | VAF 24/126 reads (19%) | called by muse, mutect2, varscan2
- ZNF816 | c.1216T>C p.Y406H | Missense Mutation (SNP) | VAF 102/222 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- ZNF831 | c.3693G>T p.W1231C | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- ZNF92 | c.1028G>T p.C343F (on ENST00000328747 / NM_152626.4; = p.C274F on NM_007139.4) | Missense Mutation (SNP) | VAF 44/274 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABHD15 | c.1239G>C p.R413= | Silent (SNP) | VAF 67/223 reads (30%) | called by muse, mutect2, varscan2
- ADAMTS19 | c.522G>T p.R174= | Silent (SNP) | VAF 89/201 reads (44%) | called by muse, mutect2, varscan2
- CARTPT | c.48G>A p.L16= | Silent (SNP) | VAF 43/316 reads (14%) | called by muse, mutect2, varscan2
- CDH7 | c.2061T>C p.T687= | Silent (SNP) | VAF 20/149 reads (13%) | catalogued as rs1270733096; called by muse, mutect2, varscan2
- CEP85L | c.180T>A p.A60= | Silent (SNP) | VAF 26/172 reads (15%) | called by muse, mutect2, varscan2
- CHADL | c.1485G>T p.G495= | Silent (SNP) | VAF 72/171 reads (42%) | called by muse, mutect2, varscan2
- CHPF | c.678G>T p.L226= | Silent (SNP) | VAF 25/123 reads (20%) | called by muse, mutect2, varscan2
- CLDND1 | c.492C>T p.C164= | Silent (SNP) | VAF 107/365 reads (29%) | called by muse, mutect2, varscan2
- CNTNAP5 | c.780G>T p.L260= | Silent (SNP) | VAF 39/136 reads (29%) | catalogued as COSV70485399; called by muse, mutect2, varscan2
- COQ3 | c.744A>G p.L248= | Silent (SNP) | VAF 49/298 reads (16%) | called by muse, mutect2, varscan2
- CPS1 | c.2409T>A p.R803= | Silent (SNP) | VAF 61/336 reads (18%) | called by muse, mutect2, varscan2
- CRYBA4 | c.321G>C p.L107= | Silent (SNP) | VAF 23/429 reads (5%) | catalogued as COSV61322604; called by muse, mutect2
- CSMD3 | c.6502C>A p.R2168= (on ENST00000297405 / NM_001363185.1; = p.R2064= on NM_052900.3) | Silent (SNP) | VAF 119/445 reads (27%) | catalogued as COSV52093221; called by muse, mutect2, varscan2
- CTNND2 | c.1479C>A p.A493= | Silent (SNP) | VAF 28/98 reads (29%) | catalogued as rs752135363, COSV58891468; called by muse, varscan2
- DCAF5 | c.2151C>T p.A717= | Silent (SNP) | VAF 119/448 reads (27%) | called by muse, mutect2, varscan2
- DLC1 | c.2571C>T p.S857= (on ENST00000276297 / NM_001348081.2; = p.S420= on NM_006094.5) | Silent (SNP) | VAF 124/420 reads (30%) | catalogued as rs745723621, COSV52292344; called by muse, mutect2, varscan2
- DLGAP2 | c.705C>A p.S235= | Silent (SNP) | VAF 45/399 reads (11%) | called by muse, mutect2, varscan2
- EBF3 | c.657C>G p.V219= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV100799115; called by muse, mutect2, varscan2
- FAM131C | c.642C>T p.P214= | Silent (SNP) | VAF 76/401 reads (19%) | called by muse, mutect2, varscan2
- FAM71A | c.451C>T p.L151= | Silent (SNP) | VAF 124/315 reads (39%) | called by muse, mutect2, varscan2
- FAM98A | c.78T>C p.D26= | Silent (SNP) | VAF 22/127 reads (17%) | catalogued as rs1283720832; called by muse, mutect2
- FCHSD1 | c.1002C>T p.S334= | Silent (SNP) | VAF 109/179 reads (61%) | called by muse, mutect2, varscan2
- FOXA2 | c.234G>T p.A78= (on ENST00000377115 / NM_153675.3; = p.A84= on NM_021784.5) | Silent (SNP) | VAF 28/146 reads (19%) | catalogued as COSV65797216; called by muse, mutect2, varscan2
- GABRA2 | c.465G>A p.L155= | Silent (SNP) | VAF 20/110 reads (18%) | catalogued as COSV62912517; called by muse, mutect2, varscan2
- GFRAL | c.774C>T p.C258= | Silent (SNP) | VAF 44/285 reads (15%) | catalogued as COSV100474473; called by muse, mutect2, varscan2
- GOLGB1 | c.8805A>G p.Q2935= | Silent (SNP) | VAF 65/220 reads (30%) | called by muse, mutect2, varscan2
- GRHL2 | c.1560G>A p.E520= | Silent (SNP) | VAF 185/555 reads (33%) | catalogued as rs1366847986; called by muse, mutect2, varscan2
- GRIN2B | c.648C>A p.I216= | Silent (SNP) | VAF 62/604 reads (10%) | called by muse, mutect2, varscan2
- GTF3C1 | c.165G>C p.P55= | Silent (SNP) | VAF 83/176 reads (47%) | catalogued as COSV99851798; called by muse, mutect2, varscan2
- HBS1L | c.2007C>T p.Y669= | Silent (SNP) | VAF 36/219 reads (16%) | catalogued as rs567806855, COSV63202524; called by muse, mutect2, varscan2
- HOXD3 | c.777G>C p.L259= | Silent (SNP) | VAF 24/181 reads (13%) | called by muse, mutect2, varscan2
- IL12B | c.291A>C p.L97= | Silent (SNP) | VAF 22/342 reads (6%) | called by muse, mutect2
- KALRN | c.7098C>T p.S2366= (on ENST00000360013 / NM_001024660.4; = p.S669= on NM_007064.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 48/168 reads (29%) | catalogued as rs762034415; called by muse, mutect2, varscan2
- KCNG1 | c.1041G>A p.A347= | Silent (SNP) | VAF 59/182 reads (32%) | called by muse, mutect2, varscan2
- KCNG1 | c.354C>T p.D118= | Silent (SNP) | VAF 35/859 reads (4%) | called by muse, mutect2
- KIAA1109 | c.4320A>G p.P1440= | Silent (SNP) | VAF 99/350 reads (28%) | called by muse, mutect2, varscan2
- LCT | c.3717G>A p.S1239= | Silent (SNP) | VAF 26/161 reads (16%) | catalogued as rs151165674, COSV51554234; called by muse, mutect2, varscan2
- LRP2 | c.9906A>G p.G3302= | Silent (SNP) | VAF 101/409 reads (25%) | called by muse, mutect2, varscan2
- LRRC56 | c.333G>A p.L111= | Silent (SNP) | VAF 56/170 reads (33%) | called by muse, mutect2, varscan2
- LVRN | c.1362T>C p.P454= | Silent (SNP) | VAF 70/164 reads (43%) | called by muse, mutect2, varscan2
- MAGEL2 | c.51C>G p.A17= | Silent (SNP) | VAF 24/50 reads (48%) | called by muse, mutect2
- MED26 | c.552G>A p.G184= | Silent (SNP) | VAF 18/153 reads (12%) | called by muse, mutect2, varscan2
- MROH9 | c.1575C>A p.I525= | Silent (SNP) | VAF 69/186 reads (37%) | catalogued as rs200769735; called by muse, mutect2, varscan2
- MUC3A | c.8784G>A p.Q2928= | Silent (SNP) | VAF 85/333 reads (26%) | called by muse, mutect2, varscan2
- MUCL3 | c.30C>G p.S10= | Silent (SNP) | VAF 21/249 reads (8%) | called by muse, mutect2
- MYPN | c.793C>T p.L265= | Silent (SNP) | VAF 39/99 reads (39%) | called by muse, mutect2, varscan2
- NMRK1 | c.246A>G p.V82= | Silent (SNP) | VAF 38/188 reads (20%) | called by muse, mutect2, varscan2
- NPIPB6 | c.96A>G p.T32= | Silent (SNP) | VAF 133/632 reads (21%) | catalogued as rs1329971764; called by muse, mutect2, varscan2
- NYNRIN | c.3516G>T p.T1172= | Silent (SNP) | VAF 96/340 reads (28%) | called by muse, mutect2, varscan2
- OR13G1 | c.186A>T p.T62= | Silent (SNP) | VAF 87/288 reads (30%) | called by muse, mutect2, varscan2
- OR2A4 | c.393T>C p.Y131= | Silent (SNP) | VAF 28/333 reads (8%) | called by muse, mutect2, varscan2
- OR4L1 | c.669C>A p.V223= | Silent (SNP) | VAF 50/193 reads (26%) | catalogued as COSV59850292, COSV59850994; called by muse, mutect2, varscan2
- OR51G2 | c.576G>A p.L192= | Silent (SNP) | VAF 41/301 reads (14%) | catalogued as rs1179825693, COSV58995399; called by muse, mutect2, varscan2
- OR52N2 | c.54C>T p.G18= | Silent (SNP) | VAF 66/212 reads (31%) | catalogued as rs372029486; called by muse, mutect2, varscan2
- PC | c.2268C>T p.V756= | Silent (SNP) | VAF 100/255 reads (39%) | catalogued as rs183729868; ClinVar: likely benign; called by muse, mutect2, varscan2
- PCDHB13 | c.1422C>T p.S474= | Silent (SNP) | VAF 73/430 reads (17%) | catalogued as COSV53399622; called by muse, mutect2, varscan2
- PGK2 | c.519T>C p.H173= | Silent (SNP) | VAF 93/230 reads (40%) | catalogued as rs909720626; called by muse, mutect2, varscan2
- PLEKHH2 | c.1758A>G p.S586= | Silent (SNP) | VAF 66/401 reads (16%) | called by muse, mutect2, varscan2
- PPP1R3A | c.2055G>A p.V685= | Silent (SNP) | VAF 187/534 reads (35%) | catalogued as COSV52887202; called by muse, mutect2, varscan2
- PPP1R3D | c.285G>C p.P95= | Silent (SNP) | VAF 20/119 reads (17%) | called by muse, mutect2, varscan2
- PRSS36 | c.2511G>T p.S837= | Silent (SNP) | VAF 25/59 reads (42%) | called by muse, mutect2, varscan2
- RNF135 | c.318C>T p.S106= | Silent (SNP) | VAF 47/512 reads (9%) | catalogued as rs1236961300; called by muse, mutect2
- RNF180 | c.519T>C p.N173= | Silent (SNP) | VAF 117/329 reads (36%) | called by muse, mutect2, varscan2
- RYR2 | c.8469C>A p.P2823= | Silent (SNP) | VAF 56/359 reads (16%) | called by muse, mutect2, varscan2
- SF3B3 | c.210G>T p.L70= | Silent (SNP) | VAF 126/340 reads (37%) | called by muse, mutect2, varscan2
- SHCBP1L | c.666G>A p.E222= | Silent (SNP) | VAF 192/434 reads (44%) | catalogued as rs377703333, COSV100772526, COSV100772527; called by muse, mutect2, varscan2
- SKIV2L | c.1854G>T p.L618= | Silent (SNP) | VAF 56/310 reads (18%) | called by muse, mutect2, varscan2
- SLC14A2 | c.159G>T p.R53= | Silent (SNP) | VAF 22/69 reads (32%) | called by muse, mutect2, varscan2
- SLC18A2 | c.615C>G p.G205= | Silent (SNP) | VAF 25/45 reads (56%) | called by muse, mutect2, varscan2
- SLC30A2 | c.36C>A p.A12= | Silent (SNP) | VAF 48/365 reads (13%) | called by muse, mutect2, varscan2
- SLCO3A1 | c.1413C>T p.C471= | Silent (SNP) | VAF 38/154 reads (25%) | called by muse, mutect2, varscan2
- SPTBN2 | c.945G>C p.S315= | Silent (SNP) | VAF 146/383 reads (38%) | catalogued as COSV59450972; called by muse, mutect2, varscan2
- SYNDIG1 | c.564C>A p.S188= | Silent (SNP) | VAF 55/255 reads (22%) | catalogued as rs1250394968, COSV100965090; called by muse, mutect2, varscan2
- TET3 | c.4056C>T p.P1352= | Silent (SNP) | VAF 74/170 reads (44%) | called by muse, mutect2, varscan2
- TRPM3 | c.2883C>T p.I961= (on ENST00000357533 / NM_001366142.2; = p.I804= on NM_020952.6) | Silent (SNP) | VAF 119/274 reads (43%) | catalogued as COSV62590019; called by muse, mutect2, varscan2
- TRPM6 | c.4389T>C p.T1463= | Silent (SNP) | VAF 253/629 reads (40%) | called by muse, mutect2, varscan2
- TTN | c.53007T>C p.Y17669= (on ENST00000591111; = p.Y10245= on NM_003319.4) | Silent (SNP) | VAF 28/132 reads (21%) | called by muse, mutect2, varscan2
- TTN | c.49080C>A p.S16360= (on ENST00000591111; = p.S8936= on NM_003319.4) | Silent (SNP) | VAF 39/159 reads (25%) | called by muse, mutect2, varscan2
- USP29 | c.1728A>G p.P576= | Silent (SNP) | VAF 89/197 reads (45%) | called by muse, mutect2, varscan2
- USP47 | c.3162G>A p.V1054= (on ENST00000399455 / NM_001372095.1; = p.V966= on NM_017944.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 26/77 reads (34%) | called by muse, varscan2
- VWCE | c.1590G>A p.E530= | Silent (SNP) | VAF 24/94 reads (26%) | called by muse, mutect2, varscan2
- WNK1 | c.1818C>G p.L606= | Silent (SNP) | VAF 20/397 reads (5%) | called by muse, mutect2
- ZBTB10 | c.1920A>G p.L640= | Silent (SNP) | VAF 111/256 reads (43%) | catalogued as rs1005391657; called by muse, mutect2, varscan2
- ZNF616 | c.2175C>T p.A725= | Silent (SNP) | VAF 68/158 reads (43%) | catalogued as rs919030593; called by muse, mutect2, varscan2
- ABCC6P1 | n.691C>T | RNA (SNP) | VAF 76/172 reads (44%) | catalogued as rs746057595; called by muse, mutect2, varscan2
- AC006288.1 | n.152G>T | RNA (SNP) | VAF 58/153 reads (38%) | called by muse, mutect2, varscan2
- AC022148.1 | n.166C>A | RNA (SNP) | VAF 51/106 reads (48%) | called by muse, mutect2, varscan2
- AC138749.1 | n.1732C>T | RNA (SNP) | VAF 94/414 reads (23%) | catalogued as rs577204367; called by muse, varscan2
- ANKRD26P1 | n.1103T>G | RNA (SNP) | VAF 65/139 reads (47%) | called by muse, mutect2, varscan2
- AP004606.1 | chr11:133532334 G>T | 5'Flank (SNP) | VAF 35/168 reads (21%) | called by muse, mutect2, varscan2
- C20orf96 | c.-25C>G | 5'UTR (SNP) | VAF 59/147 reads (40%) | catalogued as rs776840842; called by muse, mutect2, varscan2
- CAPS2 | c.648+10C>T | Intron (SNP) | VAF 48/127 reads (38%) | called by muse, mutect2, varscan2
- CCDC17 | c.1710+24G>C | Intron (SNP) | VAF 55/116 reads (47%) | called by muse, mutect2, varscan2
- CEP295 | chr11:93732033 C>T | 3'Flank (SNP) | VAF 66/192 reads (34%) | called by muse, mutect2, varscan2
- CFAP74 | c.2176+85G>T | Intron (SNP) | VAF 75/192 reads (39%) | called by muse, mutect2, varscan2
- CICP28 | chr7:56811820 G>T | 3'Flank (SNP) | VAF 48/153 reads (31%) | called by muse, mutect2, varscan2
- CLDN15 | c.382+160A>C | Intron (SNP) | VAF 24/200 reads (12%) | called by muse, mutect2, varscan2
- CLIC5 | c.1065+1513A>T | Intron (SNP) | VAF 34/218 reads (16%) | called by muse, mutect2, varscan2
- CMAHP | n.2031C>A | RNA (SNP) | VAF 36/115 reads (31%) | called by muse, mutect2, varscan2
- CSGALNACT1 | c.-194C>A | 5'UTR (SNP) | VAF 192/479 reads (40%) | called by muse, mutect2, varscan2
- CSNK2B | chr6:31665480 T>A | 5'Flank (SNP) | VAF 112/314 reads (36%) | called by muse, mutect2, varscan2
- DCUN1D4 | c.616-5835G>T | Intron (SNP) | VAF 34/100 reads (34%) | called by muse, mutect2, varscan2
- DNAJC19 | c.*43T>A | 3'UTR (SNP) | VAF 63/217 reads (29%) | called by muse, mutect2, varscan2
- DUOXA1 | chr15:45117647 C>A | 3'Flank (SNP) | VAF 37/201 reads (18%) | catalogued as COSV50993340; called by muse, mutect2, varscan2
- DUSP22 | c.-36A>T | 5'UTR (SNP) | VAF 64/347 reads (18%) | called by muse, mutect2, varscan2
- EFHC1 | c.*2700C>G | 3'UTR (SNP) | VAF 27/215 reads (13%) | called by muse, mutect2, varscan2
- EIF4G2 | chr11:10808262 C>A | 5'Flank (SNP) | VAF 32/72 reads (44%) | called by muse, mutect2, varscan2
- FHAD1 | c.4122+6161C>T | Intron (SNP) | VAF 32/56 reads (57%) | called by muse, varscan2
- GUCY1B2 | n.1330C>A | RNA (SNP) | VAF 83/206 reads (40%) | called by muse, mutect2, varscan2
- HEXA | c.254-34G>A | Intron (SNP) | VAF 86/430 reads (20%) | called by muse, mutect2, varscan2
- KCNIP4 | c.61+251154G>T | Intron (SNP) | VAF 56/165 reads (34%) | catalogued as COSV101186464; called by muse, mutect2, varscan2
- MIR518D | n.64C>G | RNA (SNP) | VAF 47/106 reads (44%) | called by muse, mutect2, varscan2
- MORF4L1 | c.466+166T>G | Intron (SNP) | VAF 41/143 reads (29%) | called by muse, mutect2, varscan2
- MUCL3 | c.946+974G>C | Intron (SNP) | VAF 70/458 reads (15%) | called by muse, mutect2, varscan2
- PIK3C3 | c.531+23G>T | Intron (SNP) | VAF 185/412 reads (45%) | catalogued as COSV100010757; called by muse, mutect2, varscan2
- PKM | c.-14+2535G>C | Intron (SNP) | VAF 13/194 reads (7%) | called by muse, mutect2
- PLPPR1 | c.-14A>G | 5'UTR (SNP) | VAF 74/180 reads (41%) | catalogued as rs766404145; called by muse, mutect2, varscan2
- PPME1 | c.835-31G>A | Intron (SNP) | VAF 20/110 reads (18%) | catalogued as rs377271302; called by muse, mutect2, varscan2
- PRMT2 | c.654+3191A>G | Intron (SNP) | VAF 26/78 reads (33%) | called by muse, mutect2, varscan2
- RN7SL106P | chr15:23163966 G>C | 5'Flank (SNP) | VAF 84/572 reads (15%) | catalogued as rs772339715; called by muse, varscan2
- SCARA5 | c.1153+24_1153+40del | Intron (DEL) | VAF 87/421 reads (21%) | called by mutect2, pindel, varscan2
- SLC6A9 | c.1654+27G>A | Intron (SNP) | VAF 8/54 reads (15%) | catalogued as rs375617488; called by muse, mutect2, varscan2
- SORCS1 | c.3371+269C>A | Intron (SNP) | VAF 63/137 reads (46%) | called by muse, varscan2
- ST6GALNAC5 | c.-31C>T | 5'UTR (SNP) | VAF 53/336 reads (16%) | called by muse, mutect2, varscan2
- TMEM18 | c.57+69G>C | Intron (SNP) | VAF 163/363 reads (45%) | called by muse, mutect2, varscan2
- TTN | c.10360+1502C>A | Intron (SNP) | VAF 58/214 reads (27%) | called by muse, mutect2, varscan2
- USH2A | c.5857+26T>C | Intron (SNP) | VAF 80/327 reads (24%) | called by muse, mutect2, varscan2
- XIRP2 | c.*1501G>T | 3'UTR (SNP) | VAF 30/108 reads (28%) | called by muse, mutect2
- ZNF204P | n.539A>T | RNA (SNP) | VAF 30/167 reads (18%) | called by muse, mutect2, varscan2
- ZNF302 | c.9+1112A>G | Intron (SNP) | VAF 10/126 reads (8%) | called by muse, mutect2
